Somatic mutation profile of tumor specimen TARGET-10-PATDDZ-09A (aliquot TARGET-10-PATDDZ-09A-01D) from TARGET case TARGET-10-PATDDZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.6 years (4,600 days).
Specimen TARGET-10-PATDDZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cccd200-dc47-42fa-8180-260bcd5ea2ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATDDZ-10A (Blood Derived Normal), aliquot TARGET-10-PATDDZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01769933-3d6c-42da-905e-d12f00adf6eb

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 3, Intron 3, Frame Shift Ins 2, RNA 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1514G>T p.R505L (on ENST00000281708 / NM_001349798.2; = p.R425L on NM_018315.5) | Missense Mutation (SNP) | VAF 31/109 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.506_507insGAGGAACC p.F169Lfs*66 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | catalogued as COSV61387105; called by mutect2, pindel
- CPNE2 | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs1245117403, COSV51964548; called by muse, mutect2, varscan2
- DMBX1 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63602502; called by muse, mutect2, varscan2
- EYS | c.4705G>T p.E1569* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as COSV58203348; called by muse, mutect2, varscan2
- KCNB2 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73049958, COSV73050429; called by muse, mutect2, varscan2
- LAMB2 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs200658738; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LOXL2 | c.1804C>A p.Q602K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1223297686, COSV66693180; called by muse, mutect2, varscan2
- LRP10 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772642452, COSV62078239; called by muse, mutect2, varscan2
- NOTCH1 | c.7318C>T p.Q2440* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV53024887; called by muse, mutect2
- RASA1 | c.633del p.R212Gfs*13 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | catalogued as COSV57202067; called by mutect2, pindel*
- SLC22A31 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs750483546; called by muse, mutect2, varscan2
- STAC2 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as rs764404407, COSV61066504; called by muse, mutect2, varscan2
- TOX3 | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54865151; called by muse, mutect2
- TTN | c.68187G>A p.W22729* (on ENST00000591111; = p.W15305* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV60292598; called by muse, mutect2, varscan2
- USP7 | c.1446_1447insTGGGG p.D483Wfs*36 | Frame Shift Ins (INS) | VAF 24/58 reads (41%) | catalogued as COSV61213215, COSV61216958; called by mutect2, pindel*, varscan2
- VCP | c.1700G>C p.R567P | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62720296, COSV62721928; called by muse, mutect2, varscan2
- NOTCH1 | c.4744_4746dup p.P1582dup | In Frame Ins (INS) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- C16orf96 | c.18G>A p.T6= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1425749217; called by muse, mutect2, varscan2
- C16orf96 | c.1935C>T p.Y645= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs769203413; called by muse, mutect2, varscan2
- GZMM | c.660C>T p.A220= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs761463798; called by muse, mutect2, varscan2
- TLR9 | c.711T>C p.P237= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as rs1425117033, COSV62348500; called by muse, mutect2
- EDF1 | c.386-131C>T | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as rs771283221; called by muse, mutect2
- NBPF7 | n.259G>T | RNA (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- PDIA3 | c.167+111C>G | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- SPATS2L | c.39+59G>T | Intron (SNP) | VAF 41/79 reads (52%) | called by muse, mutect2, varscan2
